Somatic mutation profile of tumor specimen TCGA-AB-2916-03A (aliquot TCGA-AB-2916-03A-01W-0732-08) from TCGA case TCGA-AB-2916, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myelomonocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 48.9 years (17,866 days).
Specimen TCGA-AB-2916-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 380483de-6889-4c28-876b-91083401d662.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2916-11A (Solid Tissue Normal), aliquot TCGA-AB-2916-11A-01W-0732-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/29be564e-2947-4c3d-bdad-19ce1a28e723

The open-access MAF lists 13 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 4, Silent 3, Frame Shift Ins 3, Nonsense Mutation 1, In Frame Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BTD | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.025); catalogued as COSV57728496; called by muse, mutect2, varscan2
- MYB | c.244T>C p.W82R | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57196076, COSV57197568; called by muse, mutect2, varscan2
- OR2T10 | c.771C>A p.Y257* | Nonsense Mutation (SNP) | VAF 24/52 reads (46%) | catalogued as rs765870174, COSV57896118; called by muse, mutect2, varscan2
- RUNX1T1 | c.500C>A p.S167Y (on ENST00000265814 / NM_001198628.1; = p.S140Y on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.882); catalogued as COSV56138314, COSV99750977; called by muse, mutect2, varscan2
- TRIP4 | c.271+2T>C p.X91_splice | Splice Site (SNP) | VAF 7/26 reads (27%) | catalogued as COSV56029726; called by muse, mutect2, varscan2
- WNT10A | c.152dup p.E52Gfs*29 | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | catalogued as rs749297006; called by pindel, varscan2
- BCORL1 | c.2911dup p.A971Gfs*13 | Frame Shift Ins (INS) | VAF 21/70 reads (30%) | called by mutect2, pindel, varscan2
- KIF13A | c.66_67insGGTCCC p.L22_N23insGP | In Frame Ins (INS) | VAF 5/37 reads (14%) | called by mutect2, pindel, varscan2
- RUNX1 | c.206dup p.N69Kfs*42 (on ENST00000344691 / NM_001001890.3; = p.N96Kfs*42 on NM_001754.5) | Frame Shift Ins (INS) | VAF 4/18 reads (22%) | called by mutect2, pindel, varscan2
- UFD1 | c.785A>G p.E262G | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.021); called by muse, mutect2
- CFAP46 | c.5547C>T p.S1849= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs149527720; called by muse, mutect2
- STC2 | c.717C>T p.H239= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs771024676, COSV54178394; called by muse, mutect2, varscan2
- STK39 | c.645G>A p.A215= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as rs770138220, COSV63594771; called by muse, mutect2
